Somatic mutation profile of tumor specimen 0DMKN4 from CCDI case PBCAHU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sex cord-gonadal stromal tumor, incompletely differentiated; Tissue or organ of origin: Ovary; Age at diagnosis: 14.7 years (5,379 days).
Specimen 0DMKN4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d03a00e-9acb-4331-80c1-623e0592da0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMKKI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b78953e2-72f1-437e-8909-7261e6094bf8

The open-access MAF lists 9 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5127T>A p.D1709E | Missense Mutation (SNP) | VAF 462/700 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58619194; called by muse, varscan2
- GPR135 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 287/443 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- LYPD5 | c.697G>A p.A233T (on ENST00000377950 / NM_001031749.3; = p.A190T on NM_182573.2) | Missense Mutation (SNP) | VAF 91/330 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, varscan2
- MAST1 | c.252G>A p.A84= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as rs778059086, COSV52246702; called by muse, varscan2
- PCNT | c.1149A>G p.E383= | Silent (SNP) | VAF 205/660 reads (31%) | called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 24/255 reads (9%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 26/247 reads (11%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 94/814 reads (12%) | called by muse, varscan2
- UNC13A | chr19:17688225 A>T | 5'Flank (SNP) | VAF 9/76 reads (12%) | called by muse, varscan2
